Gene-level copy-number profile of tumor specimen TCGA-AA-3862-01A from TCGA case TCGA-AA-3862, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 82.6 years (30,163 days).
Specimen TCGA-AA-3862-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.0b48696f-06ab-4146-8fca-4187550a67cb.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3862-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 363 have no estimate.
https://portal.gdc.cancer.gov/files/ddb2b7f0-044c-456c-bf20-1b88c9d7fe2c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3,097; copy number 1: 19,268; copy number 2: 36,576; copy number 3: 1,176; copy number 4: 111; copy number 6: 32.

Homozygous deletions (total copy number 0; autosomes only): 717 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:71,002,531–71,064,743, 3 genes (within-gene range 0–2): AC007881.2, OR7E91P, OR7E46P.
- chr6:14,597,514–14,599,690, 1 gene (within-gene range 0–2): AL109914.1.
- chr8:150,584–31,390,805, 712 genes (broad region; genes not listed).
- chr14:22,415,362–22,418,657, 1 gene: AC244502.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 32 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 6 (within-gene range 2–6): AC244205.1.
- chr2:88,857,161–89,177,160, 31 genes, copy number 6: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24.

Autosomal genes at a single copy (total copy number 1): 19,251. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
